Somatic mutation profile of tumor specimen TCGA-23-2641-01A (aliquot TCGA-23-2641-01A-01D-1526-09) from TCGA case TCGA-23-2641, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 85.5 years (31,232 days).
Specimen TCGA-23-2641-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1b232d10-19fe-42f6-85d0-97732299e1b8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-23-2641-10A (Blood Derived Normal), aliquot TCGA-23-2641-10A-01D-1526-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/31777873-332a-4c35-9f33-51de5b17eac4

The open-access MAF lists 101 somatic variants for this specimen: 73 protein-altering or splice-affecting, 25 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 60, Silent 25, Frame Shift Del 5, Splice Site 4, Nonsense Mutation 3, RNA 1, 3'UTR 1, Intron 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.559+1G>T p.X187_splice | Splice Site (SNP) | VAF 91/103 reads (88%) | hotspot (GDC flag); catalogued as CS137624, COSV52670017, COSV52686439, COSV52695669; called by muse, mutect2, varscan2
- ABCB1 | c.2170C>A p.L724M | Missense Mutation (SNP) | VAF 19/173 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.406); catalogued as COSV55950364; called by muse, mutect2, varscan2
- ABCC9 | c.2456G>T p.R819I | Missense Mutation (SNP) | VAF 167/379 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53970339; called by muse, mutect2, varscan2
- ANO5 | c.796C>T p.P266S | Missense Mutation (SNP) | VAF 76/178 reads (43%) | SIFT tolerated (0.8); PolyPhen benign (0.007); catalogued as COSV61084588; called by muse, mutect2, varscan2
- ARHGAP12 | c.25A>C p.K9Q | Missense Mutation (SNP) | VAF 85/174 reads (49%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.101); catalogued as COSV60963011; called by muse, mutect2, varscan2
- ASIC5 | c.1336G>T p.G446C | Missense Mutation (SNP) | VAF 27/33 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1269832909, COSV73332692; called by muse, mutect2, varscan2
- ASIP | c.387C>G p.S129R | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV100892079, COSV66588336; called by muse, varscan2
- BCAN | c.1898C>A p.T633N | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.852); catalogued as COSV100228552; called by muse, mutect2
- BCR | c.809C>G p.P270R | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); catalogued as COSV59930825; called by muse, mutect2, varscan2
- CACNG4 | c.743G>T p.R248M | Missense Mutation (SNP) | VAF 36/41 reads (88%) | SIFT deleterious (0.02); PolyPhen benign (0.299); catalogued as COSV100047922, COSV50924898; called by muse, mutect2, varscan2
- CCDC198 | c.529G>C p.E177Q | Missense Mutation (SNP) | VAF 19/321 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as rs1419912110, COSV99371430; called by muse, mutect2
- CDHR2 | c.3426G>C p.E1142D | Missense Mutation (SNP) | VAF 336/584 reads (58%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs773380209, COSV56138287; called by muse, mutect2, varscan2
- CLEC4F | c.236A>T p.N79I | Missense Mutation (SNP) | VAF 124/357 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as COSV55479172; called by muse, mutect2, varscan2
- CLPTM1L | c.796G>A p.G266R | Missense Mutation (SNP) | VAF 86/214 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1330012135, COSV100307252, COSV57990341; called by muse, mutect2, varscan2
- CNTROB | c.154G>A p.A52T | Missense Mutation (SNP) | VAF 60/78 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs770985808, COSV58050174; called by muse, mutect2, varscan2
- CYP4F8 | c.745C>A p.L249I | Missense Mutation (SNP) | VAF 46/104 reads (44%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.461); catalogued as COSV57853947; called by muse, mutect2, varscan2
- DPYSL4 | c.370C>T p.R124W | Missense Mutation (SNP) | VAF 116/229 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs537272168, COSV58307174; called by muse, mutect2, varscan2
- DYNC1H1 | c.1289T>G p.L430R | Missense Mutation (SNP) | VAF 50/103 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV64136607; called by muse, mutect2, varscan2
- EHD1 | c.938C>G p.S313C | Missense Mutation (SNP) | VAF 42/395 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV57734603; called by muse, mutect2, varscan2
- ESPL1 | c.2163T>G p.D721E | Missense Mutation (SNP) | VAF 92/300 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.039); catalogued as COSV57759192; called by muse, mutect2, varscan2
- FAM131B | c.737C>G p.A246G | Missense Mutation (SNP) | VAF 172/293 reads (59%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV58369607; called by muse, mutect2, varscan2
- FANCM | c.3778T>C p.Y1260H | Missense Mutation (SNP) | VAF 55/100 reads (55%) | SIFT tolerated (0.52); PolyPhen benign (0.04); catalogued as COSV57500656; called by muse, mutect2, varscan2
- FOXC2 | c.320C>A p.P107H | Missense Mutation (SNP) | VAF 86/107 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57444193; called by muse, mutect2, varscan2
- GIGYF1 | c.2762-1G>A p.X921_splice | Splice Site (SNP) | VAF 46/56 reads (82%) | catalogued as COSV51941443; called by muse, mutect2, varscan2
- GPR3 | c.633G>C p.Q211H | Missense Mutation (SNP) | VAF 89/192 reads (46%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV64994655; called by muse, mutect2, varscan2
- GPRIN1 | c.1840G>T p.G614W | Missense Mutation (SNP) | VAF 52/141 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV56138293, COSV56147279; called by muse, mutect2, varscan2
- GRPEL2 | c.560G>T p.G187V | Missense Mutation (SNP) | VAF 99/199 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.227); catalogued as COSV61387582; called by muse, mutect2, varscan2
- HMCN1 | c.5980A>G p.I1994V | Missense Mutation (SNP) | VAF 69/175 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV54897830; called by muse, mutect2, varscan2
- ITGAX | c.2608T>A p.F870I | Missense Mutation (SNP) | VAF 76/161 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.818); catalogued as COSV51645318; called by muse, mutect2, varscan2
- KCNQ2 | c.1777G>T p.V593L (on ENST00000359125 / NM_172107.4; = p.V565L on NM_004518.6) | Missense Mutation (SNP) | VAF 82/168 reads (49%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.879); catalogued as COSV60544228; called by muse, mutect2, varscan2
- KCNRG | c.478C>T p.Q160* | Nonsense Mutation (SNP) | VAF 85/137 reads (62%) | catalogued as COSV53949300; called by muse, mutect2, varscan2
- LAMC1 | c.1990A>G p.S664G | Missense Mutation (SNP) | VAF 56/161 reads (35%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as rs755229420, COSV51140118; called by muse, mutect2, varscan2
- LRP1 | c.12575C>T p.P4192L | Missense Mutation (SNP) | VAF 57/152 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.255); catalogued as rs762485864, COSV54503809, COSV54510117; called by muse, mutect2, varscan2
- MCF2L2 | c.1576C>G p.L526V | Missense Mutation (SNP) | VAF 127/614 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV61052910; called by muse, varscan2
- MKRN3 | c.145C>A p.P49T | Missense Mutation (SNP) | VAF 34/41 reads (83%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV58809708; called by muse, mutect2, varscan2
- MOAP1 | c.742A>G p.R248G | Missense Mutation (SNP) | VAF 9/176 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as rs754478749, COSV99365857; called by muse, mutect2
- NELL1 | c.736C>A p.L246I | Missense Mutation (SNP) | VAF 80/168 reads (48%) | SIFT tolerated (0.87); PolyPhen benign (0.197); catalogued as COSV54261065; called by muse, mutect2, varscan2
- NRBP1 | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 17/312 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.017); catalogued as COSV99275337; called by muse, mutect2
- OR10C1 | c.496T>C p.S166P (on ENST00000622521; = p.S164P on NM_013941.3) | Missense Mutation (SNP) | VAF 41/83 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.093); catalogued as rs1234651120, COSV65822727; called by muse, mutect2, varscan2
- OR1I1 | c.922G>T p.V308L | Missense Mutation (SNP) | VAF 90/216 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.018); catalogued as COSV99264937; called by muse, mutect2
- OR2G3 | c.328A>C p.T110P | Missense Mutation (SNP) | VAF 250/408 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV60681590; called by muse, mutect2, varscan2
- PBX2 | c.476C>G p.S159W | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66708880; called by muse, mutect2, varscan2
- PCDHGC5 | c.548A>G p.K183R | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV52750702; called by muse, mutect2, varscan2
- PLEKHM1 | c.3017A>T p.H1006L | Missense Mutation (SNP) | VAF 225/270 reads (83%) | SIFT tolerated (0.3); PolyPhen benign (0.334); catalogued as COSV69598826; called by muse, mutect2, varscan2
- PLOD1 | c.2026G>C p.E676Q | Missense Mutation (SNP) | VAF 171/353 reads (48%) | SIFT tolerated (0.52); PolyPhen benign (0.031); catalogued as COSV52143854; called by muse, mutect2, varscan2
- PNPLA4 | c.650T>A p.V217E | Missense Mutation (SNP) | VAF 76/96 reads (79%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV66854034; called by muse, mutect2, varscan2
- POP1 | c.1927G>C p.G643R | Missense Mutation (SNP) | VAF 87/197 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62892623; called by muse, mutect2, varscan2
- PPFIA1 | c.2134G>A p.E712K | Missense Mutation (SNP) | VAF 26/342 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.184); catalogued as COSV99558129; called by muse, mutect2
- PPP6R3 | c.1502C>G p.T501R (on ENST00000393800 / NM_001352375.2; = p.T450R on NM_018312.5) | Missense Mutation (SNP) | VAF 91/240 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.051); catalogued as COSV55725880; called by muse, mutect2, varscan2
- PRMT5 | c.659G>A p.R220H | Missense Mutation (SNP) | VAF 61/156 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs768729897, COSV53545960; called by muse, mutect2, varscan2
- PRR30 | c.1163C>A p.S388Y | Missense Mutation (SNP) | VAF 66/139 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.463); catalogued as COSV53205912; called by muse, mutect2, varscan2
- RYR1 | c.2940G>C p.Q980H | Missense Mutation (SNP) | VAF 28/48 reads (58%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.874); catalogued as COSV100617241; called by muse, mutect2
- SCN11A | c.3005G>A p.G1002D | Missense Mutation (SNP) | VAF 157/353 reads (44%) | SIFT tolerated (0.57); PolyPhen benign (0.072); catalogued as COSV100182214, COSV56569650; called by muse, mutect2, varscan2
- SIGLECL1 | c.411-1G>C p.X137_splice | Splice Site (SNP) | VAF 14/98 reads (14%) | catalogued as COSV57062791; called by muse, mutect2, varscan2
- SLC1A2 | c.690C>G p.I230M | Missense Mutation (SNP) | VAF 255/599 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.044); catalogued as COSV53521074; called by muse, mutect2, varscan2
- SUSD2 | c.1735A>G p.S579G | Missense Mutation (SNP) | VAF 140/489 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.856); catalogued as COSV64203734; called by muse, mutect2, varscan2
- TAS2R16 | c.134T>C p.V45A | Missense Mutation (SNP) | VAF 30/124 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.065); catalogued as COSV50797057, COSV99972165; called by muse, mutect2, varscan2
- TF | c.1310G>T p.C437F | Missense Mutation (SNP) | VAF 178/298 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as rs1275735351, COSV53920021; called by muse, mutect2, varscan2
- TG | c.3320C>T p.A1107V | Missense Mutation (SNP) | VAF 400/938 reads (43%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as COSV55074690; called by muse, varscan2
- TG | c.4310G>A p.W1437* | Nonsense Mutation (SNP) | VAF 521/767 reads (68%) | catalogued as CM063191, COSV55074703; called by muse, mutect2, varscan2
- TMEM38A | c.892G>T p.A298S | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.193); catalogued as COSV51818870; called by muse, mutect2, varscan2
- TRIM42 | c.1123G>T p.E375* | Nonsense Mutation (SNP) | VAF 36/132 reads (27%) | catalogued as COSV53882667, COSV53884864, COSV99648617; called by muse, mutect2, varscan2
- VGLL1 | c.416C>T p.T139I | Missense Mutation (SNP) | VAF 152/183 reads (83%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV65703229; called by muse, mutect2, varscan2
- ASAP1 | c.60-3_85del p.X20_splice | Splice Site (DEL) | VAF 42/398 reads (11%) | called by mutect2, pindel
- BBOX1 | c.668C>A p.T223K | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); called by muse, mutect2
- BRCA1 | c.2246del p.D749Vfs*4 | Frame Shift Del (DEL) | VAF 96/158 reads (61%) | called by mutect2, pindel, varscan2
- CAD | c.6591_6609del p.D2198Sfs*15 | Frame Shift Del (DEL) | VAF 8/37 reads (22%) | called by mutect2, pindel, varscan2
- CASR | c.1010_1020del p.V337Efs*17 | Frame Shift Del (DEL) | VAF 58/211 reads (27%) | called by mutect2, pindel, varscan2
- CMC4 | c.101_123del p.E34Vfs*13 | Frame Shift Del (DEL) | VAF 53/118 reads (45%) | called by mutect2, pindel, varscan2
- HTRA1 | c.905_925del p.R302_G308del | In Frame Del (DEL) | VAF 213/279 reads (76%) | called by mutect2, pindel, varscan2
- NBPF9 | c.86C>G p.A29G | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- PDE6H | c.243del p.I82Lfs*73 | Frame Shift Del (DEL) | VAF 102/338 reads (30%) | called by mutect2, pindel, varscan2
- PRAMEF14 | c.407A>G p.E136G | Missense Mutation (SNP) | VAF 95/247 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ACR | c.945C>T p.P315= | Silent (SNP) | VAF 59/75 reads (79%) | catalogued as rs1386651740, COSV53360930, COSV53361982; called by muse, mutect2, varscan2
- ARHGAP9 | c.1077C>T p.F359= | Silent (SNP) | VAF 74/144 reads (51%) | catalogued as rs1358947946, COSV57361429; called by muse, mutect2, varscan2
- C4B | c.3186G>A p.A1062= | Silent (SNP) | VAF 91/628 reads (14%) | catalogued as rs755820820, COSV70313392; called by muse, mutect2, varscan2
- CCDC58 | c.60C>T p.L20= | Silent (SNP) | VAF 15/360 reads (4%) | catalogued as rs1388849858, COSV99360455, COSV99360602; called by muse, mutect2
- CCSER2 | c.96T>C p.N32= | Silent (SNP) | VAF 10/108 reads (9%) | catalogued as COSV99826628; called by muse, mutect2
- CUX1 | c.1065G>A p.K355= (on ENST00000292535 / NM_181552.4; = p.K366= on NM_001913.5) | Silent (SNP) | VAF 153/186 reads (82%) | catalogued as COSV52898306; called by muse, mutect2, varscan2
- DST | c.2049G>A p.Q683= (on ENST00000361203 / NM_001374722.1; = p.Q357= on NM_001723.6) | Silent (SNP) | VAF 17/43 reads (40%) | catalogued as COSV55012211, COSV55012517; called by muse, mutect2, varscan2
- FRMD8 | c.1104C>T p.C368= | Silent (SNP) | VAF 41/101 reads (41%) | catalogued as COSV58212477; called by muse, mutect2, varscan2
- H3C4 | c.174G>C p.S58= | Silent (SNP) | VAF 84/184 reads (46%) | catalogued as COSV100587226, COSV61911782; called by muse, mutect2, varscan2
- HCN4 | c.3372T>G p.G1124= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as COSV99984350; called by muse, mutect2, varscan2
- IRS4 | c.1149C>T p.L383= | Silent (SNP) | VAF 36/56 reads (64%) | catalogued as rs746553866, COSV64533651; called by muse, mutect2, varscan2
- LHX1 | c.1083G>T p.L361= | Silent (SNP) | VAF 21/22 reads (95%) | catalogued as rs963847409; called by muse, mutect2, varscan2
- MYH11 | c.1731C>T p.I577= | Silent (SNP) | VAF 104/288 reads (36%) | catalogued as COSV55551949; called by muse, mutect2, varscan2
- OR4A5 | c.699C>T p.A233= | Silent (SNP) | VAF 67/151 reads (44%) | catalogued as rs757121846, COSV100156999, COSV60522408; called by muse, mutect2, varscan2
- OR56A4 | c.522C>G p.A174= | Silent (SNP) | VAF 111/138 reads (80%) | catalogued as COSV58110148; called by muse, mutect2, varscan2
- OR6C2 | c.846G>A p.L282= | Silent (SNP) | VAF 79/173 reads (46%) | catalogued as rs1214485201, COSV59515975; called by muse, mutect2, varscan2
- PCDHA9 | c.1914C>T p.D638= | Silent (SNP) | VAF 39/98 reads (40%) | catalogued as rs868952983, COSV65326170; called by muse, mutect2, varscan2
- SCN3A | c.5649C>T p.P1883= | Silent (SNP) | VAF 111/352 reads (32%) | catalogued as COSV51808783; called by muse, mutect2, varscan2
- SIGLEC9 | c.954C>T p.F318= | Silent (SNP) | VAF 17/132 reads (13%) | catalogued as COSV51584166; called by muse, mutect2, varscan2
- SLC51A | c.603C>T p.L201= | Silent (SNP) | VAF 73/354 reads (21%) | catalogued as rs780006859, COSV56351585; called by muse, mutect2, varscan2
- STYXL2 | c.1353G>C p.L451= | Silent (SNP) | VAF 29/64 reads (45%) | catalogued as COSV54804734; called by muse, mutect2, varscan2
- XPNPEP1 | c.1986C>T p.I662= | Silent (SNP) | VAF 28/180 reads (16%) | catalogued as COSV59167935; called by muse, mutect2, varscan2
- ZBTB22 | c.1707G>A p.L569= | Silent (SNP) | VAF 25/54 reads (46%) | catalogued as rs1247956923, COSV56469024; called by muse, mutect2, varscan2
- ZNF385B | c.144C>T p.F48= | Silent (SNP) | VAF 84/254 reads (33%) | catalogued as COSV69801548; called by muse, mutect2, varscan2
- ZNF703 | c.151A>C p.R51= | Silent (SNP) | VAF 25/65 reads (38%) | catalogued as COSV58998543; called by muse, mutect2, varscan2
- AL662899.2 | c.367+193C>G | Intron (SNP) | VAF 99/274 reads (36%) | catalogued as COSV65507862; called by muse, mutect2, varscan2
- CPLANE1 | c.*4787T>C | 3'UTR (SNP) | VAF 38/69 reads (55%) | catalogued as COSV57058957; called by muse, mutect2, varscan2
- DCHS2 | n.5026A>T | RNA (SNP) | VAF 44/52 reads (85%) | catalogued as COSV61771401; called by muse, mutect2, varscan2
